Surgical pathology report (de-identified scan), TCGA case TCGA-S6-A8JX, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Gundersen Lutheran Health System, specimen TCGA-S6-A8JX-01A (Primary Tumor).

[page 1 of 2]
Patient:

Med. Record No.:

Date of Birth:

Submitted by:

Report also to:

Age:

Sex: M

Pathology #:

Date of Procedure:

Date Received:

Pathology Report
**** Amended Report ****

Note: The report was amended to update the status from preliminary to final, and to include the immunohistochemistry results. The originally reported diagnosis of "seminoma" remains unchanged.

DIAGNOSIS:

SPECIMEN

Specimen type: Right radical orchiectomy

TUMOR

Histologic type: Seminoma (100% pure TSS)

Tumor size (greatest dimension): 3.4cm

Tumor focality: Multifocal

Involvement of rete testis: Present

Venous/lymphatic invasion: Present

Extent of direct tumor invasion: No direct tumor extension beyond testis

MARGINS

All margins negative for tumor

LYMPH NODES

Cannot be assessed

SERUM TUMOR MARKERS

S0: Serum marker studies within normal limits

STAGING (AJCC)

Primary Tumor: pT2

Lymph Nodes: pNX

Distant Metastasis: Cannot be assessed

ICD-0.3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
JW 1/29/14

Comment: Vascular space invasion leads to a pathologic stage of pT2.

CLINICAL INFORMATION:

Right testis mass;

research specimen

SPECIMEN(S) RECEIVED:

Right testicle and cord

Pathology Report

[page 2 of 2]
Patient: [REDACTED]

MRN: [REDACTED]

GROSS DESCRIPTION:

Received fresh is a 35-gram radical orchiectomy consisting of a 4.5 x 3.5 x 3 cm testis, 5 x 1 x 0.5 cm epididymis and 13 x 1.2 cm spermatic cord. The glistening, pink-purple tunica vaginalis retracts with ease revealing a smooth, glistening, pink-gray tunica albuginea. The majority of the testis has been replaced by a firm, nodular 3.4 x 3.3 x 2.7 cm gray-white mass which appears grossly to extend within 0.1 cm of the tunica albuginea. The epididymis and spermatic cord are grossly uninvolved by tumor. The testicular parenchyma unaffected by tumor is soft, stringy and golden brown. There are a few smaller, tan-gray nodules present at the periphery of the main mass measuring up to 0.5 cm. Multiple representative sections are submitted: A1 – spermatic cord margin; A2 – mid spermatic cord; A3 – spermatic cord near testis; A4-A5 – mass with adjacent epididymis and tunica vaginalis; A6-A7 – mass with adjacent smaller nodules.

Immunohistochemistry Results

Formalin-fixed, paraffin-embedded tissue is utilized. Tissue sections are incubated with the following antibodies. Controls stain appropriately. Complete procedural methodology is available upon request. Results indicated below:

Material: Block A7

Marker For:	Result	Comment
Placental alkaline phosphatase (PLAP)	Positive	
Human chorionic gonadotropin (HCG)	Negative	
Alpha-fetoprotein (AFP)	Negative	
CD30	Negative	
Cytokeratins (pan-keratin cocktail)	Negative	

Note: The performance characteristics of all immunohistochemical stains cited in this report were determined by the [REDACTED], as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88). Some of these tests may rely on the use of "analyte specific reagents" and have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to this report. These tests are used for clinical purposes and should not be regarded as investigational or for research. The immunohistochemistry laboratory at [REDACTED] is certified by the Centers for Medicare and Medicaid Services (formerly HCFA) as a high complexity laboratory under CLIA 00.

Slides were microscopically examined by the pathologist.

Amendment reported by [REDACTED]

Electronically signed

Criteria	hw 8/2/13	Yes	No
HI/PA Discrepancy			✓

Pathology Report

Source: NCI Genomic Data Commons file 57124880-6d6c-4598-b390-44c772254608 (TCGA-S6-A8JX.FCF21848-5F0A-4730-9507-2FD898FCDAF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).